Somatic mutation profile of tumor specimen C3N-01003-01 (aliquot CPT0078610009) from CPTAC case C3N-01003, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IVB; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 73.9 years (26,984 days).
Specimen C3N-01003-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6252636-9a7d-482e-a89c-98b38b205446.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01003-31 (Blood Derived Normal), aliquot CPT0078650002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6afa8b56-1897-4ee4-ab52-2ebf089a6825

The open-access MAF lists 67 somatic variants for this specimen: 46 protein-altering or splice-affecting, 13 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 13, Frame Shift Del 6, Intron 5, Splice Site 3, Nonsense Mutation 3, Frame Shift Ins 1, RNA 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 35/234 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATP13A2 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 77/501 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.174); catalogued as rs536805463; called by muse, mutect2, varscan2
- CDK10 | c.608+1G>T p.X203_splice (on ENST00000353379 / NM_052988.5; = p.X132_splice on NM_052987.4) | Splice Site (SNP) | VAF 30/308 reads (10%) | catalogued as rs771066826; called by muse, mutect2
- CFAP46 | c.3557G>A p.R1186H | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.558); catalogued as rs554361204; called by muse, mutect2, varscan2
- DNMBP | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); catalogued as rs953581942; called by muse, mutect2, varscan2
- HEXD | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.106); catalogued as rs376222154; called by muse, mutect2, varscan2
- IGHV1-3 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 82/616 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs782691780; called by muse, mutect2, varscan2
- IGLV2-18 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 74/534 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.229); catalogued as rs373202759; called by muse, mutect2, varscan2
- KCNH4 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0.006); catalogued as rs756662029, COSV52918193; called by muse, mutect2, varscan2
- NINL | c.2476A>T p.M826L | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770860358; called by muse, mutect2, varscan2
- OR2T3 | c.543T>A p.S181R | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs1174992028; called by muse, mutect2, varscan2
- PLEC | c.12217G>A p.A4073T (on ENST00000322810 / NM_201380.4; = p.A3963T on NM_000445.5) | Missense Mutation (SNP) | VAF 19/611 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs368314247; ClinVar: uncertain significance; called by muse, mutect2
- RNF220 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs752576898, COSV62404408, COSV62404590; called by muse, mutect2, varscan2
- TYW1 | c.1198T>C p.Y400H | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99053992; called by muse, mutect2
- ZFAND2A | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 15/207 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs527420198, COSV57180070, COSV57180704; called by muse, mutect2
- ACADL | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANTXRL | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 80/290 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARID1A | c.5898del p.L1967Cfs*48 | Frame Shift Del (DEL) | VAF 48/403 reads (12%) | called by mutect2, pindel, varscan2
- CCDC138 | c.267-4_270delinsTTTTTTTT p.X89_splice | Splice Site (ONP) | VAF 4/49 reads (8%) | called by mutect2*, pindel
- DNAH17 | c.10417G>C p.V3473L | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNASE1 | c.613T>C p.S205P | Missense Mutation (SNP) | VAF 135/516 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- GLT8D2 | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- GNAS | c.1717G>A p.D573N | Missense Mutation (SNP) | VAF 96/768 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- H4C4 | c.191A>G p.E64G | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- IFNAR1 | c.900del p.G301Efs*22 | Frame Shift Del (DEL) | VAF 22/53 reads (42%) | called by mutect2, pindel, varscan2
- IQCJ-SCHIP1 | c.1005_1008del p.R335Sfs*39 (on ENST00000485419 / NM_001197113.1; = p.R259Sfs*39 on NM_014575.3) | Frame Shift Del (DEL) | VAF 16/121 reads (13%) | called by mutect2, pindel, varscan2
- ITGA9 | c.1727A>G p.E576G | Missense Mutation (SNP) | VAF 200/657 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- KRT73 | c.611T>A p.L204Q | Missense Mutation (SNP) | VAF 124/430 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KTN1 | c.1579_1580insCC p.N527Tfs*25 | Frame Shift Ins (INS) | VAF 3/37 reads (8%) | called by mutect2, pindel
- MAP3K3 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.558); called by muse, mutect2
- MSC | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MYLK | c.1807_1811del p.K603Efs*2 | Frame Shift Del (DEL) | VAF 89/391 reads (23%) | called by mutect2, pindel, varscan2
- NAV1 | c.4670C>T p.S1557L | Missense Mutation (SNP) | VAF 59/454 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- NDUFB5 | c.181A>G p.R61G | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH17 | c.796A>C p.N266H | Missense Mutation (SNP) | VAF 61/495 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PEAK1 | c.3719C>G p.T1240S | Missense Mutation (SNP) | VAF 46/275 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PLB1 | c.2061C>A p.N687K | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2
- POLQ | c.5681G>T p.G1894V | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2
- PUS3 | c.436A>C p.N146H | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, varscan2
- SHB | c.875_876del p.K292Rfs*6 | Frame Shift Del (DEL) | VAF 30/255 reads (12%) | called by mutect2, pindel, varscan2
- SHCBP1 | c.1257_1275del p.K419Nfs*12 | Frame Shift Del (DEL) | VAF 14/134 reads (10%) | called by mutect2, pindel
- SLC1A5 | c.825G>A p.W275* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- TECR | c.664+1_664+2delinsC p.X222_splice | Splice Site (DEL) | VAF 59/664 reads (9%) | called by pindel, varscan2*
- TTC28 | c.3895G>A p.V1299I | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- VARS1 | c.1251G>A p.W417* | Nonsense Mutation (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2, varscan2
- CORIN | c.1119C>T p.D373= | Silent (SNP) | VAF 32/218 reads (15%) | catalogued as rs773680908, COSV56688927; called by muse, mutect2, varscan2
- DGKZ | c.2583G>A p.P861= (on ENST00000454345 / NM_001105540.2; = p.P673= on NM_003646.4) | Silent (SNP) | VAF 72/225 reads (32%) | catalogued as rs775551960; called by muse, mutect2, varscan2
- GALNT11 | c.681A>G p.R227= | Silent (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- INPPL1 | c.3435C>T p.L1145= | Silent (SNP) | VAF 15/145 reads (10%) | called by muse, mutect2, varscan2
- L1CAM | c.3711G>A p.A1237= | Silent (SNP) | VAF 53/179 reads (30%) | catalogued as rs782576787; ClinVar: likely benign; called by muse, mutect2, varscan2
- MORN1 | c.195G>A p.A65= | Silent (SNP) | VAF 30/251 reads (12%) | catalogued as rs1393492545, COSV58100158; called by muse, mutect2, varscan2
- MUC22 | c.4176C>T p.G1392= | Silent (SNP) | VAF 37/352 reads (11%) | called by muse, mutect2, varscan2
- OTUB1 | c.684C>T p.S228= | Silent (SNP) | VAF 83/309 reads (27%) | catalogued as rs200423792, COSV55362192; called by muse, mutect2, varscan2
- PAK3 | c.66C>T p.N22= | Silent (SNP) | VAF 122/385 reads (32%) | catalogued as COSV99457925; called by muse, mutect2, varscan2
- PAPOLB | c.603C>T p.S201= | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as rs1361532184; called by muse, mutect2, varscan2
- TMIGD1 | c.174C>T p.N58= | Silent (SNP) | VAF 78/297 reads (26%) | called by muse, mutect2, varscan2
- ULK4 | c.480G>A p.E160= | Silent (SNP) | VAF 28/104 reads (27%) | called by muse, mutect2, varscan2
- VWA3B | c.2962C>T p.L988= | Silent (SNP) | VAF 12/340 reads (4%) | called by muse, mutect2
- ABI3BP | c.1576+9227G>A | Intron (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849798 G>A | 5'Flank (SNP) | VAF 25/226 reads (11%) | called by muse, mutect2, varscan2
- C20orf27 | c.19+18G>A | Intron (SNP) | VAF 18/155 reads (12%) | catalogued as rs139106660; called by muse, mutect2, varscan2
- MAPT | c.220+2491_220+2504del | Intron (DEL) | VAF 48/349 reads (14%) | called by mutect2, pindel
- PRPF40A | c.276+49G>A | Intron (SNP) | VAF 48/455 reads (11%) | called by muse, mutect2, varscan2
- RPL23AP87 | n.1604T>C | RNA (SNP) | VAF 101/413 reads (24%) | called by muse, mutect2, varscan2
- STAR | c.65-32_65-31del | Intron (DEL) | VAF 67/300 reads (22%) | called by mutect2, pindel, varscan2
- TAZ | c.*417C>T | 3'UTR (SNP) | VAF 169/656 reads (26%) | called by muse, mutect2, varscan2
